TCGA case TCGA-WK-A8XZ — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Brigham and Women's Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0a4af73d-3c12-4740-bf92-c0eedd3dd135

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Dead; Days to death: 1,722 days (4.7 years).

Diagnoses (7)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.4; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of abdomen; Classification of tumor: primary; Age at diagnosis: 56.0 years (20,460 days); Year of diagnosis: 2007; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Inferior Vena Cava; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 10; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Tumor burden: 6.2.
   Pathology details: Measurement type: Pathologic; Tumor burden: 9.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 9.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Skin of scalp and neck. Age at diagnosis: 56.3 years (20,549 days); Days to diagnosis: 89 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 58.0 years (21,180 days); Days to diagnosis: 720 days (2.0 years); Prior treatment: Yes.
4. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Connective, subcutaneous and other soft tissues of abdomen. Age at diagnosis: 58.2 years (21,250 days); Days to diagnosis: 790 days (2.2 years); Prior treatment: Yes.
5. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Bone, NOS. Age at diagnosis: 59.0 years (21,562 days); Days to diagnosis: 1,102 days (3.0 years); Prior treatment: Yes.
6. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 59.0 years (21,562 days); Days to diagnosis: 1,102 days (3.0 years); Prior treatment: Yes.
7. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Pelvis, NOS. Age at diagnosis: 59.0 years (21,562 days); Days to diagnosis: 1,102 days (3.0 years); Prior treatment: Yes.

Follow-up (7 entries)
- Day 89 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin of scalp and neck; Days to progression: 89 days.
- Day 720 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 720 days (2.0 years).
- Day 790 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of abdomen; Days to recurrence: 790 days (2.2 years).
- Day 1,102 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,102 days (3.0 years).
- Day 1,102 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 1,102 days (3.0 years).
- Day 1,102 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,102 days (3.0 years).
- Days to follow up: 1,722 days (4.7 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 39.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WK-A8XZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 50 mg.
  Slide TCGA-WK-A8XZ-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WK-A8XZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WK-A8XZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: Inferior vena cava; Site of primary tumor other: Inferior vena cava; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Contiguous organ resection: Kidney; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum; Submitted tumor site: Retroperitoneum/Upper abdominal - Other (please specify.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 9.
- Radiation treatment: Days from index date to radiation therapy started: 59; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,722 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,722 days; disease-free interval: event (new tumor event after initially disease-free), 89 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 89 days.
